Somatic mutation profile of tumor specimen TCGA-VT-A80J-02A (aliquot TCGA-VT-A80J-02A-11D-A417-09) from TCGA case TCGA-VT-A80J, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 49.1 years (17,925 days).
Specimen TCGA-VT-A80J-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1353498c-25db-416c-a499-7889835ad67d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VT-A80J-11A (Solid Tissue Normal), aliquot TCGA-VT-A80J-11A-22D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bb0e5bd-3b2f-4498-8785-c956b3d0989b

The open-access MAF lists 48 somatic variants for this specimen: 36 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 11, Nonsense Mutation 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.537T>G p.H179Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs876660821, CM0910925, COSV52669519, COSV52673406, COSV53016879; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC006059.2 | c.154C>A p.Q52K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.364); catalogued as COSV100045142; called by muse, mutect2
- ACCS | c.1126G>T p.V376L | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV99772642; called by muse, mutect2, varscan2
- AHNAK2 | c.8329T>C p.S2777P | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs564635013, COSV100315553; called by muse, mutect2, varscan2
- ANG | c.386T>A p.V129D | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100390815; called by muse, mutect2, varscan2
- APLNR | c.899T>C p.V300A | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV57244270; called by muse, varscan2
- BMP6 | c.346C>A p.Q116K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.009); catalogued as COSV99306324; called by muse, mutect2, varscan2
- CDH26 | c.2188C>G p.P730A (on ENST00000348616 / NM_177980.4; = p.P63A on NM_021810.6) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0.083); catalogued as COSV99721781; called by muse, mutect2, varscan2
- CHD5 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs141210110, COSV99314074; called by muse, varscan2
- CLDN6 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 51/71 reads (72%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV58510316; called by muse, mutect2, varscan2
- CPS1 | c.4203C>A p.N1401K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV99242156; called by muse, mutect2
- CTDP1 | c.2795G>T p.S932I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99310108; called by muse, mutect2, varscan2
- ECM1 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 34/76 reads (45%) | catalogued as COSV100681630; called by muse, mutect2, varscan2
- FAM210B | c.384C>G p.I128M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.42); catalogued as COSV100452761, COSV57168039; called by mutect2, varscan2
- GINS1 | c.448-2A>G p.X150_splice | Splice Site (SNP) | VAF 12/53 reads (23%) | catalogued as COSV99319948; called by muse, mutect2, varscan2
- KHDRBS1 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.22); catalogued as COSV100306100; called by muse, mutect2, varscan2
- LIN37 | c.421C>G p.P141A | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99137377; called by muse, mutect2, varscan2
- LRIT2 | c.980G>A p.C327Y | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100258399; called by muse, mutect2, varscan2
- MAGED1 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.019); catalogued as COSV100431378; called by muse, mutect2, varscan2
- MYL1 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV100751498; called by muse, mutect2, varscan2
- MYO5C | c.3544C>T p.H1182Y | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV55902509; called by muse, mutect2, varscan2
- NLGN3 | c.1554G>A p.W518* (on ENST00000358741 / NM_181303.2; = p.W498* on NM_018977.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 33/75 reads (44%) | catalogued as COSV100704545; called by muse, mutect2, varscan2
- NPFFR2 | c.1045T>C p.F349L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.27); catalogued as COSV100440299, COSV100440960; called by muse, mutect2, varscan2
- OTUD6A | c.110A>T p.D37V | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100610929; called by muse, mutect2
- PGM3 | c.1069C>A p.H357N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99392172; called by muse, mutect2
- PRAMEF14 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1283917666; called by muse, mutect2, varscan2
- R3HDM1 | c.1178G>A p.S393N | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51533243, COSV99925676; called by muse, mutect2, varscan2
- RAI1 | c.1712C>G p.S571C | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99883330; called by muse, mutect2, varscan2
- RET | c.681G>C p.W227C | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.619); catalogued as COSV100392268; called by muse, mutect2
- SASH1 | c.1211G>T p.R404I | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772766127, COSV100820894; called by muse, mutect2, varscan2
- SCGN | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs200726171; called by muse, mutect2, varscan2
- SHANK1 | c.866T>C p.M289T | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as rs927786260, COSV99520181; called by muse, mutect2, varscan2
- SP140 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100613356; called by muse, mutect2
- TM2D1 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 84/171 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV99623333; called by muse, mutect2, varscan2
- TRPM6 | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV100665330; called by muse, mutect2, varscan2
- UBXN4 | c.905A>G p.Q302R | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99738657; called by muse, mutect2, varscan2
- ADCY8 | c.681C>T p.C227= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV53904553; called by muse, mutect2, varscan2
- BTBD2 | c.906G>A p.T302= | Silent (SNP) | VAF 53/102 reads (52%) | catalogued as rs763587966, COSV99724512; called by muse, mutect2, varscan2
- DLGAP2 | c.300T>C p.G100= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as COSV101421019; called by muse, mutect2, varscan2
- EPB41L1 | c.36G>A p.K12= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV99148928; called by muse, mutect2, varscan2
- FILIP1 | c.2217T>C p.D739= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV99383851; called by muse, mutect2, varscan2
- FLG2 | c.1896C>G p.G632= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as COSV101165591, COSV66171895; called by muse, mutect2, varscan2
- HIPK4 | c.768C>T p.D256= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs377700394; called by muse, mutect2, varscan2
- IGLV3-1 | c.60C>T p.S20= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs577917177; called by muse, mutect2, varscan2
- MUC17 | c.3810C>A p.T1270= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as COSV100071580, COSV60306270; called by muse, mutect2, varscan2
- MYH2 | c.4806C>T p.S1602= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as COSV99819253; called by muse, mutect2, varscan2
- ZCCHC12 | c.813C>T p.D271= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs1174068367, COSV59571255, COSV59572524; called by muse, mutect2, varscan2
- DOCK4 | c.2736+3931T>G | Intron (SNP) | VAF 11/137 reads (8%) | called by muse, mutect2
